Gene-level copy-number profile of tumor specimen TCGA-HT-A4DV-01A from TCGA case TCGA-HT-A4DV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.5 years (18,799 days).
Specimen TCGA-HT-A4DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.15a111c4-d61b-4df1-8c31-c96edbf2f10d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-A4DV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 406 have no estimate.
https://portal.gdc.cancer.gov/files/161c6d1e-6204-4804-b46b-85f51a840e4e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,283; copy number 1: 3,060; copy number 2: 54,134; copy number 3: 449; copy number 5: 77; copy number 6: 77; copy number 7: 6; copy number 8: 15; copy number 9: 6; copy number 10: 91; copy number 11: 18; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 1,762 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,276,859–121,580,524, 1,746 genes (broad region; genes not listed).
- chr1:153,031,203–153,057,512, 3 genes: SPRR1B, SPRR2D, SPRR2A.
- chr3:101,457,241–101,458,626, 2 genes: AC110994.2, Y_RNA.
- chr4:45,480,030–45,480,136, 1 gene: RNU6-931P.
- chr5:127,588,746–127,590,710, 1 gene: AC010424.3.
- chr10:121,133,090–121,133,723, 1 gene: RPL19P16.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:55,635,113–55,674,675, 4 genes: OR4P4, OR4S2, OR4C6, OR4V1P.
- chr22:24,691,122–24,712,520, 3 genes (within-gene range 0–2): AP000357.2, AP000358.1, CRIP1P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 285 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:189,764,391–190,092,279, 23 genes, copy number 6 (within-gene range 2–6): FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr6:116,249,964–116,254,075, 1 gene, copy number 9: TSPYL4.
- chr6:116,258,493–116,279,930, 2 genes, copy number 9: AL050331.1, TSPYL1.
- chr8:150,584–202,897, 5 genes, copy number 11: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1.
- chr8:46,028,804–46,028,892, 1 gene, copy number 6: AC118650.1.
- chr9:60,914,407–64,498,745, 92 genes, copy number 5–8 (broad region; genes not listed).
- chr12:38,078,529–38,167,631, 6 genes, copy number 7: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359.
- chr14:65,411,170–65,471,186, 3 genes, copy number 9: FUT8-AS1, RPL21P8, MIR625.
- chr14:105,736,343–106,622,855, 144 genes, copy number 5–10 (broad region; genes not listed).
- chr15:25,239,838–25,250,940, 7 genes, copy number 11: SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:14,988,259–14,990,160, 1 gene, copy number 26: AC138932.2.

Autosomal genes at a single copy (total copy number 1): 3,060. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
